FM case AD14676 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum.
https://portal.gdc.cancer.gov/cases/22b1240d-e691-4790-b386-a88aa962dab1

Male, 57.6 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the rectum; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
